Gene-level copy-number profile of tumor specimen C3L-02644-02 (profiled together with C3L-02644-03, C3L-02644-05) from CPTAC case C3L-02644, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 58.1 years (21,234 days).
Specimen C3L-02644-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 3d553302-7d76-4b4d-b668-1f7ada93aced.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-02644-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,226 have no estimate.
https://portal.gdc.cancer.gov/files/29071b7b-4023-44eb-aa04-c806d39da2c9

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 17; copy number 1: 7,252; copy number 2: 47,532; copy number 3: 3,159; copy number 4: 38; copy number 5: 213; copy number 6: 33; copy number 7: 48; copy number 8: 67; copy number 9: 3; copy number 10: 35.

Homozygous deletions (total copy number 0; autosomes only): 17 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,966,929–22,128,103, 8 genes (within-gene range 0–1): CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.
- chr10:48,040,462–48,040,577, 1 gene: RNA5SP315.
- chr12:11,351,823–11,395,566, 1 gene (within-gene range 0–1): PRB1.
- chr17:31,094,927–31,382,116, 7 genes (within-gene range 0–1): NF1, AC079915.1, OMG, EVI2B, AC134669.1, EVI2A, AK4P1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 399 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:54,009,789–54,064,605, 2 genes, copy number 8 (within-gene range 2–8): CHIC2, AC110792.2.
- chr4:54,229,280–56,710,614, 55 genes, copy number 8 (within-gene range 2–8): PDGFRA, LINC02283, AC098587.1, AC098868.1, LINC02260, KIT, AC097494.1, LINC02358, AC111194.1, RPL38P3, RNU6-410P, AC111194.2, RN7SL424P, KDR, RN7SL822P, AC021220.1, RNU6-746P, LRRC34P2, SRD5A3, FCF1P8, SRD5A3-AS1, AC069200.1, TMEM165, Y_RNA, CLOCK, Y_RNA, RN7SKP30, AC024243.1, PDCL2, NMU, RNU6-276P, EXOC1L, EXOC1, RNU6-652P, AC110611.1, CEP135, CRACD, RNA5SP161, RNU6-197P, AC022267.1, MRPL22P1, AASDH, RPL7AP31, AC068620.1, PPAT, AC068620.2, AC068620.3, PAICS, SRP72, ARL9, THEGL, GLDCP1, HOPX, AC108215.1, RPL17P20.
- chr17:9,822,206–19,756,207, 342 genes, copy number 5–10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 7,252. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
